Gene-level copy-number profile of tumor specimen TCGA-XU-A92W-01A from TCGA case TCGA-XU-A92W, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 61.7 years (22,554 days).
Specimen TCGA-XU-A92W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THYM.cf115f03-756d-4736-9c89-098a5cd49c40.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XU-A92W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/542b1809-0526-4c06-a1be-691dcb251e00

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,429; copy number 2: 57,373.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XU-A92W-01A-11D-A422-01): tumor purity 0.62, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 43. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
